Surgical pathology report (de-identified scan), TCGA case TCGA-74-6577, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Swedish Neurosciences, specimen TCGA-74-6577-01A (Primary Tumor).

[page 1 of 3]
Encounter Date: [REDACTED]

Results: PATHOLOGY / NON GYN
CYTOLOGY [REDACTED]

Status: [REDACTED]

TCGA-74-6577

Collection Information

Collection Date [REDACTED]

Collection Time: [REDACTED]

Lab Information

Lab [REDACTED]

Component Results

SURGICAL PATHOLOGY
REPORT

Case Number: [REDACTED]

Procedures/Addenda Present

Collected: [REDACTED]

Received: [REDACTED]

Signed Out: [REDACTED]

Reported: [REDACTED]

CLINICAL INFORMATION:

Neoplasm of unspecified nature of brain.

ICD-9 code: 239.6

INTRAPROCEDURAL CONSULTATION:

- A. Right frontal brain tumor (frozen section and touch preparation):
Highly necrotic tumor consistent with glioblastoma.
- B. Right frontal brain tumor (frozen section and touch preparation):
Glioblastoma.

GROSS DESCRIPTION:

- A. Received fresh, labeled [REDACTED] designated "A. right frontal brain tumor", are four fragments of irregular soft tan tissue measuring up to 0.6 cm in greatest dimension. Approximately a third of the specimen is submitted for frozen section and submitted in cassette AFS. The remainder of the unfrozen tissue is submitted in cassette A1.
- B. Received fresh, labeled [REDACTED] designated 3B. right frontal brain tumor, are four fragments of irregular soft tan tissue measuring up to 0.6 cm in greatest dimension. Approximately a third of the specimen is submitted for frozen section and submitted in cassette BFS. A touch preparation is performed. A representative section is frozen and entirely submitted in BFS. The remainder of the unfrozen tissue is submitted in cassette B1. Submitted later are portions of cerebral cortex and white matter measuring up to 2.0 x 0.8 cm to 5.5 x 2.9 x 1.7 cm. All portions have white focally hemorrhagic friable soft tissue, which extend into the underlying brain tissue. The remaining representative sections are submitted in B2-B8.
- C. Received in formalin, labeled [REDACTED] designated 3C. CUSA contents, is a 7 cc aggregate of tan irregular soft tissue which is submitted in total in C1-C7.

MICROSCOPIC DESCRIPTION:

The immunohistochemical tests reported were developed and performance characteristics determined by [REDACTED]. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests may be used for clinical purposes. They should not be regarded as investigational or for research use only. [REDACTED] is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA) as qualified to perform high complexity clinical laboratory testing.

[page 2 of 3]
FINAL PATHOLOGIC DIAGNOSIS:

- A. Brain, right frontal lobe, tumor, biopsy:
B. Brain, right frontal lobe, tumor, resection:
C. Brain, CUSA contents:
-Glioblastoma, WHO grade IV/IV with the following features:
-Degree of cellularity: High.
-Microvascular proliferation: Present.
-Necrosis: Present with pseudopalisading.
-Mitotic rate: Up to 19 per 10 high power fields.
-Other features:
-p53 is positive in tumor (part B).
-FISH and MGMT studies (PCR and immunohistochemistry) are pending.

COMMENT:

Immunostains to chromogranin and synaptophysin (block B4) show weak positive staining within the tumor suggesting foci of 3neural4 differentiation.

Electronically Signed By

PROCEDURES/ADDENDA:

ICC- IMMUNOHISTOCHEMISTRY Date Ordered: [REDACTED] Status:

Date Complete: [REDACTED]

By: [REDACTED]

Date Reported: [REDACTED]

Interpretation

B. RIGHT FRONTAL BRAIN TUMOR, IMMUNOHISTOCHEMISTRY

RESULTS:

-TUMOR IS POSITIVE FOR MGMT BY IMMUNOHISTOCHEMISTRY (30% OF TUMOR).

FISH Date Ordered: [REDACTED]

Status: [REDACTED]

Date Complete: [REDACTED]

By: [REDACTED]

Date Reported: [REDACTED]

* Amended *

Interpretation

B. Right frontal lobe brain tumor, FISH results:

- Negative for 1p/19q codeletion.
- Positive for polysomy 1 and 19.
- Positive for polysomy 7/EGFR.
- Positive for monosomy 10/PTEN.

Results-Comments

[page 3 of 3]
Encounter Date: [REDACTED]

At the request of [REDACTED] representative sections of the tumor (block B4) were submitted for FISH analysis. The results are consistent with the stated diagnosis. Please see separate report by [REDACTED]

Amendments for FISH [REDACTED]

Amended: [REDACTED]

Reason: Miscellaneous

CORRECT PHYSICIAN ADDED

Previous Signout Date: [REDACTED]

MGMT by PCR Date Ordered: [REDACTED]

Status: [REDACTED]

Date Complete: [REDACTED]

By: [REDACTED]

Date Reported: [REDACTED]

Interpretation
{Not Entered}

Results-Comments

B. RIGHT FRONTAL BRAIN TUMOR, MGMT Methylation Assay results:
-Gene Methylation NOT detected.

Please see full report from [REDACTED] for additional details accession [REDACTED]

This order has external results.

[Lab Inquiry](#)

[View Complete Results](#)

Results

Order Details

Order Details

[REDACTED]		Dept Phone	[REDACTED]	Description	[REDACTED]
Hospital		Encounter	[REDACTED]	Department	[REDACTED]
Encounter	[REDACTED]				
MRN	[REDACTED]				

Order

PATHOLOGY / NON GYN CYTOLOGY [REDACTED]

Source: NCI Genomic Data Commons file 6215eaf4-094c-4856-9c06-98137578a656 (TCGA-74-6577.0FE10A6D-E211-43C7-8A89-56ED221CBB96.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).